TCGA case TCGA-BR-6709 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Asterand. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/6f70e9f0-580b-4199-934b-dacd29fb28a0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Ukraine; Age at index: 57 years; Vital status: Dead; Days to death: 370 days (1.0 years); Cause of death: Cancer Related.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 57.3 years (20,935 days); Year of diagnosis: 2011; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N3a; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 15; Lymph nodes tested: 15.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Cisplatin + Fluorouracil; Days to treatment start: 61 days; Days to treatment end: 206 days; Treatment outcome: Partial Response.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Leucovorin; Days to treatment start: 61 days; Days to treatment end: 206 days; Treatment outcome: Partial Response.
   Recorded as not given: adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 38 days; Disease response: With Tumor.
- Days to follow up: 370 days (1.0 years); Disease response: With Tumor.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BR-6709-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 2.5; Intermediate dimension: 1.4; Shortest dimension: 0.5.
  Slide TCGA-BR-6709-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-BR-6709-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 70; Percent normal cells: 5; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-BR-6709-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BR-6709-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-BR-6709-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1.6; Intermediate dimension: 1.1; Shortest dimension: 0.5.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: With tumor; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Kiev; Number of relatives with stomach cancer: 0.
- Drug treatment 1: Pharmaceutical therapy drug name: 5-Fluorouracil.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: With tumor; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Progressive Disease; Cause of death: Stomach Cancer.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 370 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 370 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 370 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BR-6709-01A-11D-1881-01): tumor purity 0.32, ploidy 1.93, whole-genome doublings 0.
